CCDI case PBCKDY — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Thyroid gland.
https://portal.gdc.cancer.gov/cases/279692f1-c3e0-4134-bb9e-f350a7216b7a

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Papillary carcinoma, NOS: ICD-O-3 morphology code: 8050/3; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 15.0 years (5,494 days).

Biospecimens (4 samples)
- Samples 0DTYAN, 0DVPOQ (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DTYAX: Tissue type: Normal; Specimen type: Peripheral Whole Blood. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample 0DTYB9: Tissue type: Tumor; Specimen type: Solid Tissue. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
